Somatic mutation profile of tumor specimen C3L-03272-02 (aliquot CPT0225380006) from CPTAC case C3L-03272, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,779 days).
Specimen C3L-03272-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddb8f747-0a9c-4611-b1ab-fac0dc0d1059.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03272-31 (Blood Derived Normal), aliquot CPT0226050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c194b73-4f77-4816-8958-7b72c68b0458

The open-access MAF lists 343 somatic variants for this specimen: 233 protein-altering or splice-affecting, 58 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 204, Silent 58, Intron 21, Nonsense Mutation 15, 5'UTR 11, RNA 8, 5'Flank 7, Splice Site 5, Frame Shift Del 4, 3'UTR 3, Splice Region 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52746396; called by muse, mutect2, varscan2
- AMY2A | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV101340686, COSV70214852; called by mutect2, varscan2
- APC2 | c.4375G>A p.G1459S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1225234024; called by muse, mutect2, varscan2
- BSN | c.3743C>T p.T1248M | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs755975338; called by muse, mutect2, varscan2
- C12orf60 | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs1206675271; called by muse, mutect2, varscan2
- CACNB2 | c.296C>A p.A99E (on ENST00000324631 / NM_201596.3; = p.A44E on NM_000724.4) | Missense Mutation (SNP) | VAF 150/557 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as COSV56620035, COSV56624648; called by muse, varscan2
- CCDC170 | c.1898T>A p.M633K | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV99498940; called by muse, mutect2, varscan2
- CCR2 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52749516; called by muse, mutect2, varscan2
- CELSR1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1399025271; called by muse, mutect2, varscan2
- CNTN3 | c.2131G>T p.G711C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361500708; called by muse, mutect2, varscan2
- COL27A1 | c.2851A>T p.M951L | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV61923071; called by muse, mutect2, varscan2
- CSMD3 | c.6058A>G p.S2020G (on ENST00000297405 / NM_001363185.1; = p.S1916G on NM_052900.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99835216; called by muse, mutect2, varscan2
- CWC22 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.151); catalogued as COSV55431827; called by muse, mutect2, varscan2
- CXorf58 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64858469; called by muse, mutect2, varscan2
- DCAF12L1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV64422859; called by muse, varscan2
- DCDC1 | c.4589C>T p.T1530I (on ENST00000597505 / NM_001367979.1; = p.T637I on NM_020869.3) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV57998266; called by muse, mutect2, varscan2
- DMD | c.7244G>A p.R2415H | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373749120, COSV58899961; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- DNAH10 | c.12872C>A p.P4291H (on ENST00000409039; = p.P4230H on NM_207437.3) | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99436057; called by muse, mutect2, varscan2
- ELFN1 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.115); catalogued as rs1373515462; called by muse, mutect2
- ERMAP | c.1048C>A p.R350S | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.58); catalogued as COSV60275387; called by muse, mutect2, varscan2
- FGD5 | c.3977G>T p.R1326L | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV99548170; called by muse, mutect2, varscan2
- FGG | c.123+1G>T p.X41_splice | Splice Site (SNP) | VAF 25/153 reads (16%) | catalogued as CS002448; called by muse, mutect2, varscan2
- GCK | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 28/169 reads (17%) | catalogued as CM096796, CM930301; called by muse, varscan2
- GLCCI1 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1202587719; called by muse, mutect2
- HK2 | c.11C>G p.S4W | Missense Mutation (SNP) | VAF 80/482 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.559); catalogued as COSV51878239, COSV51878851; called by muse, mutect2, varscan2
- HSPA13 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV53466529; called by muse, mutect2, varscan2
- IFIH1 | c.394A>T p.R132* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV55130848; called by muse, mutect2, varscan2
- KAT6A | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs753934123; called by muse, varscan2
- KCNK10 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs758531762, COSV56649268; called by muse, mutect2, varscan2
- KLHL32 | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV100987306; called by muse, mutect2, varscan2
- LAMC3 | c.3968C>T p.S1323L | Missense Mutation (SNP) | VAF 123/452 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as rs1302978418, COSV62654603; called by muse, mutect2, varscan2
- LYN | c.1001A>T p.D334V | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs750361940; called by muse, mutect2
- MARCO | c.734C>G p.T245S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs1217378583; called by muse, mutect2, varscan2
- MAST3 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451525511; called by muse, mutect2, varscan2
- MB21D2 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as rs377569367, COSV66663425, COSV66665491; called by muse, mutect2, varscan2
- MICAL2 | c.2192G>C p.R731P | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200483678; called by muse, mutect2, varscan2
- MINAR1 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.558); catalogued as COSV59586752; called by muse, mutect2
- MROH5 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs776389636, COSV101436213; called by muse, mutect2, varscan2
- MYH1 | c.3848G>T p.R1283L | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56847132; called by muse, mutect2, varscan2
- MYH13 | c.5667G>T p.A1889= | Splice Region (SNP) | VAF 21/97 reads (22%) | catalogued as COSV52822581; called by muse, mutect2, varscan2
- MYH7B | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV53418585; called by muse, mutect2, varscan2
- NLRP5 | c.1933del p.V645* | Frame Shift Del (DEL) | VAF 35/151 reads (23%) | catalogued as COSV66762308; called by mutect2, pindel, varscan2
- NOP53 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as rs1230100395; called by muse, mutect2, varscan2
- NRG1 | c.1653del p.K551Nfs*32 (on ENST00000405005 / NM_013964.5; = p.K556Nfs*32 on NM_013956.5) | Frame Shift Del (DEL) | VAF 42/203 reads (21%) | catalogued as COSV55169214; called by mutect2, pindel, varscan2
- OR1L4 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 51/373 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99413879; called by muse, mutect2, varscan2
- OR2M3 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as rs202069600; called by muse, mutect2, varscan2
- OR4N2 | c.507T>A p.C169* | Nonsense Mutation (SNP) | VAF 50/472 reads (11%) | catalogued as COSV60055179; called by muse, mutect2, varscan2
- OR5D13 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV62335019; called by muse, mutect2, varscan2
- PCDH11X | c.2182C>A p.Q728K | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100008453; called by muse, mutect2, varscan2
- PCDH15 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.349); catalogued as COSV57294912; called by muse, mutect2, varscan2
- PCDHA5 | c.2120C>A p.S707Y | Missense Mutation (SNP) | VAF 82/399 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65351465, COSV65351605; called by muse, mutect2, varscan2
- PEAR1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs913658222; called by muse, mutect2
- PFAS | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV58983827; called by muse, mutect2, varscan2
- PLCD3 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs770340208; called by muse, mutect2, varscan2
- PLCH1 | c.3373G>A p.G1125R (on ENST00000340059 / NM_001130960.2; = p.G1117R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV58187431, COSV58208271; called by muse, mutect2, varscan2
- PNLIPRP3 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755781497; called by muse, mutect2
- POGLUT3 | c.721G>T p.G241* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV60213055; called by muse, mutect2, varscan2
- PTCHD3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.971); catalogued as COSV101438942; called by muse, mutect2
- RAD21 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV99815661; called by muse, mutect2, varscan2
- RNF43 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.154); catalogued as COSV68458494; called by muse, mutect2, varscan2
- RXFP3 | c.647C>A p.A216E | Missense Mutation (SNP) | VAF 41/390 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.384); catalogued as rs761225440, COSV57506132; called by muse, mutect2, varscan2
- SCN1A | c.98A>T p.K33M | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57671694; called by muse, mutect2
- SIAH3 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs751758471; called by muse, mutect2, varscan2
- SLC22A15 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs767735362, COSV65680152, COSV65680535; called by muse, mutect2, varscan2
- SLCO1C1 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); catalogued as COSV56868156; called by muse, mutect2, varscan2
- ST14 | c.2200G>T p.D734Y | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV53836655; called by muse, mutect2, varscan2
- ST8SIA3 | c.563G>C p.R188P | Missense Mutation (SNP) | VAF 20/102 reads (20%) | PolyPhen probably damaging (1); catalogued as COSV60653708; called by muse, mutect2, varscan2
- STAT5A | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1434706212, COSV61805687; called by muse, mutect2
- STEAP4 | c.666C>A p.D222E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs370475892, COSV57328085; called by mutect2, varscan2
- SUPT20HL2 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775539283; called by muse, varscan2
- THSD4 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780022155; called by muse, mutect2, varscan2
- TJP3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs759077725; called by muse, mutect2, varscan2
- TLN1 | c.5041G>T p.A1681S | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.262); catalogued as COSV59211854; called by muse, mutect2, varscan2
- TNR | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 36/269 reads (13%) | catalogued as COSV54888727, COSV99688167; called by muse, mutect2, varscan2
- TROAP | c.1123G>T p.V375F | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.167); catalogued as rs748113634; called by muse, mutect2, varscan2
- TTN | c.81905C>T p.P27302L (on ENST00000591111; = p.P19878L on NM_003319.4) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | PolyPhen probably damaging (1); catalogued as rs917359469, COSV100591842; called by muse, mutect2, varscan2
- VWA3B | c.3767G>A p.R1256H | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.009); catalogued as rs1189775076, COSV71366941; called by muse, mutect2, varscan2
- ZC3H7B | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as rs1420650539; called by muse, mutect2, varscan2
- ZMYM3 | c.3340G>T p.G1114C | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58739280; called by muse, mutect2, varscan2
- ZNF282 | c.1963G>T p.G655C | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV100021811; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.637T>C p.C213R | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs914129420; called by muse, mutect2, varscan2
- ZNF646 | c.3917G>A p.R1306Q | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs774977140, COSV54924685; called by muse, mutect2, varscan2
- ZNF776 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs746768569; called by muse, mutect2, varscan2
- ZNF804B | c.1229G>T p.R410I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV60837662; called by muse, mutect2, varscan2
- ABCB8 | c.1510G>T p.A504S (on ENST00000297504 / NM_001282291.2; = p.A487S on NM_007188.5) | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM1 | c.1474C>G p.P492A | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ADGRB3 | c.2069T>A p.M690K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB3 | c.2231G>T p.S744I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- AIMP2 | c.92A>G p.H31R | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- AJAP1 | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AKAP4 | c.1874A>G p.D625G | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALMS1 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 25/154 reads (16%) | called by muse, mutect2, varscan2
- ANK2 | c.11735G>T p.G3912V | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKFN1 | c.2125C>A p.Q709K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.115); called by muse, mutect2
- ANPEP | c.2372A>T p.N791I | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ARHGAP25 | c.1063C>A p.P355T (on ENST00000409202 / NM_001007231.3; = p.P347T on NM_014882.3) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMH3 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- BHLHE23 | c.549G>T p.L183F (on ENST00000370346; = p.L199F on NM_080606.4) | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- C16orf92 | c.322G>C p.V108L | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C2orf81 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- C5orf22 | c.247dup p.W83Lfs*55 | Frame Shift Ins (INS) | VAF 22/114 reads (19%) | called by mutect2, pindel
- CCDC168 | c.19159G>A p.G6387S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CCNJL | c.251C>G p.T84S | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CDC73 | c.1553T>A p.L518* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- CEP97 | c.253T>G p.L85V | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD4 | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CHD9 | c.7313T>C p.V2438A (on ENST00000398510 / NM_001382353.1; = p.V2422A on NM_025134.7) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CNDP2 | c.1044G>T p.M348I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- CNTN3 | c.1171A>G p.K391E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- CNTN4 | c.1417G>T p.G473W | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN6 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL9A1 | c.2686G>A p.G896R | Missense Mutation (SNP) | VAF 80/380 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYBG2 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- CTNND2 | c.230C>A p.A77D | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, varscan2
- DCST1 | c.1495A>C p.S499R | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DENND4A | c.1806A>T p.Q602H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLGAP3 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMKN | c.578G>A p.W193* | Nonsense Mutation (SNP) | VAF 30/356 reads (8%) | called by muse, mutect2
- DNAJA1 | c.348A>C p.E116D | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DPP6 | c.1327G>A p.G443S (on ENST00000377770 / NM_001364500.2; = p.G381S on NM_001936.5) | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECSIT | c.1293C>A p.S431R | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2
- EIF4B | c.1792G>T p.V598F | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ENO2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 91/404 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- EXO1 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM110A | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM126B | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- FAM133B | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 77/337 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM186A | c.5012dup p.L1671Ffs*25 | Frame Shift Ins (INS) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- FAM83H | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 185/445 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L5 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GABRB3 | c.158G>T p.R53I | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GCH1 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDAP1L1 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- GOLGA6L2 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 107/271 reads (39%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- GOLIM4 | c.1987G>T p.D663Y | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- GPR1 | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- GRIA1 | c.1299C>A p.D433E | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- H1-10 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HHLA1 | c.5T>C p.L2P | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGCR | c.2299-2A>G p.X767_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- HTR1E | c.1054A>T p.K352* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- IFT52 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGFL3 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IGFL3 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- IGKV1D-17 | c.297C>G p.S99R | Missense Mutation (SNP) | VAF 70/421 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IL18R1 | c.720G>T p.L240F | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- IRF4 | c.638-2A>T p.X213_splice | Splice Site (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- IRX5 | c.1073C>G p.P358R | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ITGA1 | c.3056C>G p.P1019R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ITGBL1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- JUNB | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 83/469 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KANSL1 | c.2441C>A p.T814N | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- KCNT2 | c.1865A>T p.K622I | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KEAP1 | c.1612G>C p.D538H | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIR2DL1 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2
- KLHL1 | c.1067A>T p.E356V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LBX1 | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 35/354 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LCK | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); called by muse, mutect2
- LPXN | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP4 | c.2516G>T p.R839L | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAGEB2 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAP3K8 | c.527C>A p.P176Q | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.609); called by muse, varscan2
- MDN1 | c.2648T>A p.M883K | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM2 | c.4838C>T p.A1613V | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NMS | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- NOMO1 | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 42/236 reads (18%) | called by muse, mutect2, varscan2
- NPAS3 | c.2198C>A p.A733D (on ENST00000356141 / NM_001164749.2; = p.A701D on NM_022123.3) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- NTNG1 | c.1388A>G p.Q463R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NUDT13 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NYAP2 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR11L1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OR13H1 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR51D1 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- OR56A3 | c.557T>A p.M186K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- OR5AR1 | c.864G>C p.L288F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2
- OR5L2 | c.168C>G p.H56Q | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OR6F1 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OXA1L | c.1130T>G p.M377R (on ENST00000285848; = p.M317R on NM_005015.5) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); called by muse, mutect2
- PARVG | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 49/222 reads (22%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1482G>T p.Q494H | Missense Mutation (SNP) | VAF 126/627 reads (20%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PDCD1 | c.754G>T p.V252F | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDZD7 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); called by muse, mutect2
- PDZRN3 | c.2865C>A p.S955R | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- PHF23 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PKHD1L1 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2
- PLCH1 | c.4987G>T p.G1663C (on ENST00000340059 / NM_001130960.2; = p.G1655C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- PNLIPRP1 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PPP1R21 | c.2268A>T p.L756F (on ENST00000294952 / NM_001135629.3; = p.L745F on NM_152994.5) | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM9 | c.1181G>T p.C394F | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- PRM2 | c.272del p.G91Afs*36 | Frame Shift Del (DEL) | VAF 62/424 reads (15%) | called by pindel, varscan2
- PRRC2C | c.4726A>G p.R1576G (on ENST00000367742; = p.R1574G on NM_015172.4) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, varscan2
- PSD2 | c.1217T>C p.I406T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PTPRM | c.3311G>T p.C1104F | Missense Mutation (SNP) | VAF 86/368 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTX3 | c.552A>C p.L184F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- RBM42 | c.1312_1313del p.A438Hfs*3 | Frame Shift Del (DEL) | VAF 20/136 reads (15%) | called by pindel, varscan2
- RBMXL3 | c.3016G>T p.G1006C | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- RECQL4 | c.1759G>T p.A587S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RNF123 | c.3929C>T p.T1310I | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RP1 | c.1709T>C p.I570T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SALL1 | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2, varscan2
- SDR39U1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SERPINI2 | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SGCB | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGK1 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SI | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- SIRT1 | c.952C>G p.P318A | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A7 | c.428T>A p.M143K | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2
- SLITRK3 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 15/308 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2
- SSTR1 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SYNE1 | c.7808C>T p.T2603I (on ENST00000367255 / NM_182961.4; = p.T2610I on NM_033071.3) | Missense Mutation (SNP) | VAF 60/356 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SYNE3 | c.2657A>T p.K886M | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYPL2 | c.776G>C p.S259T | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TDRD6 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TECPR2 | c.2866C>T p.L956F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- THSD7A | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2
- THSD7A | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TINF2 | c.391A>T p.K131* | Nonsense Mutation (SNP) | VAF 92/341 reads (27%) | called by muse, mutect2, varscan2
- TMEM130 | c.897C>A p.Y299* | Nonsense Mutation (SNP) | VAF 43/190 reads (23%) | called by muse, mutect2, varscan2
- TMEM161B | c.446+1G>T p.X149_splice | Splice Site (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2
- TMEM87A | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TMPRSS2 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRGV3 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TRIM51GP | c.779T>A p.L260Q | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- TTC14 | c.858-6T>C | Splice Region (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- UGT1A8 | c.584T>C p.L195S | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- UPF1 | c.2758A>G p.S920G (on ENST00000599848 / NM_001297549.2; = p.S909G on NM_002911.4) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- UPRT | c.724+1G>T p.X242_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- USP13 | c.333G>T p.R111S | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- YWHAZ | c.455C>G p.A152G | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- ZNF467 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF48 | c.1118C>A p.T373N | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF496 | c.192G>T p.W64C | Missense Mutation (SNP) | VAF 48/534 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2
- ZNF541 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2
- ACSM1 | c.1686C>A p.G562= | Silent (SNP) | VAF 32/229 reads (14%) | called by muse, mutect2, varscan2
- ADRB3 | c.630C>T p.S210= | Silent (SNP) | VAF 104/482 reads (22%) | catalogued as rs1376364083, COSV61462652; called by muse, mutect2, varscan2
- AJAP1 | c.222C>A p.V74= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- AOC1 | c.1029A>T p.G343= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV100710954; called by muse, mutect2, varscan2
- ARID4A | c.54C>A p.A18= | Silent (SNP) | VAF 26/185 reads (14%) | called by muse, mutect2
- CDH7 | c.1296G>T p.G432= | Silent (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- CENPB | c.42A>G p.S14= | Silent (SNP) | VAF 114/348 reads (33%) | catalogued as COSV60144273; called by muse, mutect2, varscan2
- CHD4 | c.12C>T p.G4= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as rs1411810014; called by muse, mutect2, varscan2
- CRAMP1 | c.1410C>T p.G470= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs768542850; called by muse, mutect2, varscan2
- CRYBG2 | c.2469G>T p.L823= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- CSNK1A1L | c.996T>C p.N332= | Silent (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- CTSO | c.849A>G p.P283= | Silent (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- CYFIP2 | c.600T>C p.D200= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- DCAF12L1 | c.174G>A p.R58= | Silent (SNP) | VAF 58/147 reads (39%) | called by muse, varscan2
- DMBT1 | c.108G>A p.S36= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs746899807; called by mutect2, varscan2
- DNAH14 | c.1866C>T p.I622= (on ENST00000445597; = p.I651= on NM_001367479.1) | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs1206060961; called by muse, mutect2
- DOCK2 | c.948G>A p.T316= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs199921409, COSV56951428; called by muse, mutect2, varscan2
- DPP9 | c.651C>T p.G217= (on ENST00000598800; = p.G246= on NM_139159.5) | Silent (SNP) | VAF 82/258 reads (32%) | catalogued as rs368915583, COSV53591384; called by muse, mutect2, varscan2
- EFCAB3 | c.360G>A p.K120= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs766225409; called by muse, mutect2, varscan2
- FBXO41 | c.2139C>T p.I713= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as rs768629603, COSV54584099; called by muse, mutect2, varscan2
- FHOD3 | c.3960G>T p.S1320= (on ENST00000359247 / NM_001281739.3; = p.S1337= on NM_025135.5) | Silent (SNP) | VAF 45/215 reads (21%) | catalogued as rs1053933786; called by muse, mutect2, varscan2
- FSHR | c.108G>A p.K36= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as rs1281533376, COSV100437713; called by muse, mutect2, varscan2
- KIAA0753 | c.1128G>A p.K376= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV100810696; called by muse, mutect2, varscan2
- LILRA4 | c.1167C>T p.H389= | Silent (SNP) | VAF 85/616 reads (14%) | catalogued as rs771948059, COSV52492975; called by muse, varscan2
- LRRC4C | c.1299G>C p.G433= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV53432112; called by muse, mutect2, varscan2
- LRRIQ3 | c.882T>A p.P294= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- MCHR1 | c.330C>A p.I110= | Silent (SNP) | VAF 93/357 reads (26%) | called by muse, mutect2, varscan2
- METTL14 | c.660A>G p.E220= | Silent (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2
- MGMT | c.195G>T p.L65= (on ENST00000306010; = p.L34= on NM_002412.5) | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- MS4A3 | c.123A>G p.P41= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- NFKBIZ | c.1209C>T p.N403= | Silent (SNP) | VAF 25/206 reads (12%) | called by muse, mutect2, varscan2
- NOG | c.135C>T p.D45= | Silent (SNP) | VAF 101/479 reads (21%) | called by muse, mutect2, varscan2
- NXPE4 | c.288C>T p.S96= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as rs376142309; called by muse, mutect2, varscan2
- OR2L2 | c.48G>T p.L16= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- OR51D1 | c.483C>A p.A161= | Silent (SNP) | VAF 71/241 reads (29%) | called by muse, mutect2, varscan2
- OR52I2 | c.900C>A p.P300= | Silent (SNP) | VAF 61/237 reads (26%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.363C>T p.A121= | Silent (SNP) | VAF 114/442 reads (26%) | called by muse, mutect2, varscan2
- PSD2 | c.489G>A p.G163= | Silent (SNP) | VAF 42/208 reads (20%) | called by muse, mutect2, varscan2
- PXDNL | c.207C>A p.A69= | Silent (SNP) | VAF 32/174 reads (18%) | called by muse, mutect2, varscan2
- REG3A | c.315G>T p.G105= | Silent (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- RSPH6A | c.654C>T p.Y218= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs772831381; called by muse, mutect2, varscan2
- RTN4IP1 | c.1077G>A p.A359= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs778714437, COSV100954245, COSV64805770; called by muse, mutect2, varscan2
- SEZ6L2 | c.1989C>A p.I663= (on ENST00000308713 / NM_001114099.3; = p.I593= on NM_012410.4) | Silent (SNP) | VAF 63/300 reads (21%) | called by mutect2, varscan2
- SGCD | c.117G>A p.L39= (on ENST00000435422 / NM_001128209.2; = p.L40= on NM_000337.5) | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- SNTG2 | c.510G>A p.G170= | Silent (SNP) | VAF 29/181 reads (16%) | catalogued as COSV57997205; called by muse, mutect2, varscan2
- STOX2 | c.351G>T p.R117= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- STXBP1 | c.1215C>T p.I405= | Silent (SNP) | VAF 91/309 reads (29%) | called by muse, mutect2, varscan2
- TEP1 | c.2022G>T p.L674= | Silent (SNP) | VAF 23/212 reads (11%) | called by muse, mutect2, varscan2
- TGIF2LY | c.141A>G p.P47= | Silent (SNP) | VAF 63/230 reads (27%) | called by muse, mutect2, varscan2
- TJP2 | c.3336G>A p.Q1112= | Silent (SNP) | VAF 125/349 reads (36%) | called by muse, mutect2, varscan2
- TMUB2 | c.117G>T p.V39= (on ENST00000538716 / NM_001353177.2; = p.V19= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 51/251 reads (20%) | called by muse, mutect2, varscan2
- TRIM44 | c.411A>G p.Q137= | Silent (SNP) | VAF 41/173 reads (24%) | called by muse, mutect2, varscan2
- VNN2 | c.925C>T p.L309= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as rs749819919; called by muse, mutect2, varscan2
- ZACN | c.66C>A p.V22= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- ZNF362 | c.534A>T p.T178= | Silent (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2
- ZNF479 | c.786T>A p.T262= | Silent (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- ZNF831 | c.4866T>A p.T1622= | Silent (SNP) | VAF 35/170 reads (21%) | called by muse, mutect2, varscan2
- ZSCAN20 | c.165G>A p.R55= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as rs763207013; called by muse, mutect2, varscan2
- ABCC8 | c.2694+19G>A | Intron (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2, varscan2
- AC026410.1 | n.771C>T | RNA (SNP) | VAF 69/314 reads (22%) | catalogued as rs574066216; called by muse, mutect2, varscan2
- ACTG1P17 | n.822A>G | RNA (SNP) | VAF 44/137 reads (32%) | catalogued as rs776429841; called by muse, mutect2, varscan2
- ACTR3BP2 | n.943T>A | RNA (SNP) | VAF 21/130 reads (16%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1259C>A | Intron (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- ANGEL2 | c.712+38A>T | Intron (SNP) | VAF 19/87 reads (22%) | catalogued as rs1558184596; called by mutect2, varscan2
- ANKRD20A2P | c.-55G>A | 5'UTR (SNP) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- AP000769.5 | chr11:65499111 A>T | 5'Flank (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- AQP4 | c.33-40G>T | Intron (SNP) | VAF 40/247 reads (16%) | called by muse, mutect2, varscan2
- BNC2 | c.130-49C>G | Intron (SNP) | VAF 40/164 reads (24%) | catalogued as rs755308937; called by muse, mutect2, varscan2
- C6orf201 | c.285-6358G>A | Intron (SNP) | VAF 43/141 reads (30%) | called by muse, mutect2, varscan2
- CHMP1A | c.7+87G>T | Intron (SNP) | VAF 58/168 reads (35%) | catalogued as COSV53683885; called by muse, mutect2, varscan2
- CIB4 | c.186+5841C>A | Intron (SNP) | VAF 32/177 reads (18%) | called by muse, mutect2, varscan2
- CORO1A | chr16:30183018 G>T | 5'Flank (SNP) | VAF 44/254 reads (17%) | called by muse, mutect2
- CSH1 | c.457-35C>T | Intron (SNP) | VAF 45/471 reads (10%) | catalogued as rs749564716, COSV60241902; called by muse, mutect2
- DIMT1 | c.792+221C>T | Intron (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- DIS3L2 | c.2497-231C>T | Intron (SNP) | VAF 39/194 reads (20%) | called by muse, mutect2, varscan2
- EIF4A2 | c.-3A>G | 5'UTR (SNP) | VAF 262/477 reads (55%) | catalogued as rs768461790; called by muse, mutect2, varscan2
- FBLN1 | c.1698-11245A>T | Intron (SNP) | VAF 39/284 reads (14%) | called by muse, mutect2, varscan2
- GP2 | chr16:20327530 C>T | 5'Flank (SNP) | VAF 27/153 reads (18%) | catalogued as rs1461766150; called by muse, mutect2, varscan2
- GSTZ1 | c.15+231G>T | Intron (SNP) | VAF 40/202 reads (20%) | called by muse, mutect2, varscan2
- HPN | c.161-151C>A | Intron (SNP) | VAF 34/174 reads (20%) | called by muse, varscan2
- IGKV2-29 | n.76C>A | RNA (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- IQCD | c.963+28C>T | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as rs754441889; called by muse, mutect2, varscan2
- KAT5 | c.79+146C>G | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- MIR1915 | chr10:21495769 C>A | 3'Flank (SNP) | VAF 46/268 reads (17%) | catalogued as rs752200671; called by muse, mutect2
- MIR6511A3 | chr16:16371642 C>G | 3'Flank (SNP) | VAF 44/1037 reads (4%) | called by muse, mutect2
- MME | c.*2C>T | 3'UTR (SNP) | VAF 29/248 reads (12%) | called by muse, mutect2, varscan2
- MTCH1 | c.-37C>A | 5'UTR (SNP) | VAF 42/219 reads (19%) | catalogued as rs1463377057; called by muse, mutect2, varscan2
- MTO1 | c.217+28G>A | Intron (SNP) | VAF 54/220 reads (25%) | catalogued as rs765942243; called by muse, mutect2, varscan2
- MYADML | n.905G>A | RNA (SNP) | VAF 84/456 reads (18%) | catalogued as rs192862884; called by muse, mutect2, varscan2
- PATZ1 | chr22:31347006 C>A | 5'Flank (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- PLEKHO1 | c.-17G>T | 5'UTR (SNP) | VAF 11/31 reads (35%) | catalogued as rs1344742755; called by muse, mutect2, varscan2
- POTEM | c.811-1194C>A | Intron (SNP) | VAF 24/452 reads (5%) | called by muse, mutect2
- PSMD4 | c.-36C>T | 5'UTR (SNP) | VAF 36/202 reads (18%) | called by muse, mutect2, varscan2
- PSMD4 | c.-35C>T | 5'UTR (SNP) | VAF 36/203 reads (18%) | called by muse, mutect2, varscan2
- PTCH2 | c.-27G>T | 5'UTR (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2, varscan2
- PTGES3 | c.-28G>A | 5'UTR (SNP) | VAF 20/82 reads (24%) | catalogued as rs767425892; called by muse, varscan2
- RAB17 | c.*480G>A | 3'UTR (SNP) | VAF 28/146 reads (19%) | called by muse, mutect2
- RAD21 | chr8:116874890 C>T | 5'Flank (SNP) | VAF 48/225 reads (21%) | catalogued as rs574205761; called by muse, mutect2, varscan2
- RING1 | chr6:33207922 G>T | 5'Flank (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1911C>A | RNA (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- SHCBP1L | chr1:182953332 C>A | 5'Flank (SNP) | VAF 8/36 reads (22%) | catalogued as COSV62356080; called by muse, mutect2, varscan2
- SLC25A21 | c.-12C>A | 5'UTR (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3489G>T | RNA (SNP) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- SPATA31C2 | n.834C>T | RNA (SNP) | VAF 82/928 reads (9%) | catalogued as rs1303819463; called by muse, mutect2
- SPINK2 | c.55+64C>T | Intron (SNP) | VAF 69/431 reads (16%) | catalogued as rs778789852; called by muse, varscan2
- TCIRG1 | c.*30T>C | 3'UTR (SNP) | VAF 99/372 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.10360+3603C>A | Intron (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- UNC93B1 | c.-22C>T | 5'UTR (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- WDR41 | c.-14C>T | 5'UTR (SNP) | VAF 39/123 reads (32%) | called by muse, mutect2, varscan2
- ZFYVE16 | c.2581+567C>G | Intron (SNP) | VAF 37/156 reads (24%) | called by muse, mutect2, varscan2
